Somatic mutation profile of tumor specimen TCGA-A6-5664-01A (aliquot TCGA-A6-5664-01A-21D-1835-10) from TCGA case TCGA-A6-5664, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 80.6 years (29,426 days).
Specimen TCGA-A6-5664-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c11a73c-a610-419a-94ba-732c58f054de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-5664-10A (Blood Derived Normal), aliquot TCGA-A6-5664-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3841f42d-a070-4765-8a7f-6b3730264d30

The open-access MAF lists 52 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 33, Silent 11, Nonsense Mutation 6, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 15/93 reads (16%) | hotspot (GDC flag); catalogued as rs587781392, CM920027, COSV57321978; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.3341C>T p.T1114M | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386833752, CM094697, COSV67503825; ClinVar: likely pathogenic / pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 26/70 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic; called by muse, mutect2
- ACE | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as rs1478780828, COSV99326968; called by muse, mutect2, varscan2
- ACKR2 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as rs772013246, COSV56177434; called by muse, mutect2, varscan2
- AKR1D1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs146935906; called by muse, mutect2, varscan2
- BPIFB4 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs779403776, COSV64951593; called by muse, mutect2, varscan2
- C7 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV100495774; called by muse, mutect2, varscan2
- CATSPERD | c.2223C>A p.Y741* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as rs1365148387, COSV58465778; called by muse, mutect2, varscan2
- CCNT1 | c.965A>G p.N322S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99980729; called by muse, mutect2, varscan2
- DNAH5 | c.9287G>A p.R3096Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs1388732051, COSV54203252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH8 | c.13372C>T p.R4458* | Nonsense Mutation (SNP) | VAF 15/77 reads (19%) | catalogued as rs369355205, COSV100545093; called by muse, mutect2, varscan2
- DNAJC2 | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); catalogued as COSV50786498, COSV50788423; called by muse, mutect2, varscan2
- FARP1 | c.2689C>T p.R897C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100130613; called by muse, mutect2
- FAT3 | c.4723G>T p.V1575L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV53125772; called by muse, mutect2, varscan2
- FBN3 | c.3400G>A p.G1134S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768183863, COSV104374155; called by mutect2, varscan2
- GRIN2A | c.3020A>G p.N1007S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV100409707; called by muse, mutect2, varscan2
- HOOK3 | c.1902A>C p.K634N | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56883591; called by muse, mutect2, varscan2
- INTS4 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 22/232 reads (9%) | catalogued as rs772470786, COSV71087785, COSV71089033; called by muse, mutect2
- MIS18BP1 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs780491734, COSV60371416; called by muse, mutect2, varscan2
- MYH1 | c.2869G>T p.D957Y | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99875875; called by muse, mutect2, varscan2
- MYLK | c.4079G>A p.G1360D | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782967, COSV60612967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRX1 | c.2193C>G p.N731K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1227445513, COSV52705787; called by muse, mutect2, varscan2
- OR2T6 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs865984223, COSV100861560, COSV63216427; called by muse, mutect2
- PCDHA11 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1187011496, COSV56481398; called by muse, mutect2, varscan2
- POU4F2 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.31); catalogued as rs760611375, COSV55585072; called by muse, mutect2
- PTGER3 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV60688334, COSV60693133; called by muse, mutect2, varscan2
- RCBTB1 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1047582495, COSV51634133; called by muse, mutect2, varscan2
- RPS6KA1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201278235; called by muse, mutect2, varscan2
- SAP130 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as rs376315873; called by muse, mutect2, varscan2
- SENP5 | c.1331A>G p.E444G | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.138); catalogued as COSV100051977; called by mutect2, varscan2
- SLC12A2 | c.3212+1G>A p.X1071_splice | Splice Site (SNP) | VAF 7/80 reads (9%) | catalogued as rs1197640923, COSV52472529; called by muse, mutect2
- SMAD4 | c.1018A>G p.K340E | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61689631; called by muse, mutect2, varscan2
- SULT1E1 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56947612, COSV99894941; called by muse, mutect2, varscan2
- TESPA1 | c.1234G>T p.E412* (on ENST00000316577 / NM_001098815.3; = p.E274* on NM_014796.2 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/140 reads (17%) | catalogued as COSV100345214; called by muse, mutect2, varscan2
- TRIM60 | c.996A>T p.R332S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV100594015; called by muse, mutect2
- TRPV1 | c.1106A>G p.K369R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs533984481, COSV51519782; called by muse, mutect2, varscan2
- ZNF646 | c.3739A>G p.N1247D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99762278; called by muse, varscan2
- ZNFX1 | c.5066T>C p.L1689P | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65602034; called by muse, mutect2
- CACNA1F | c.4226_4227del p.E1409Vfs*5 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by pindel, varscan2
- BEND6 | c.600T>G p.L200= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV66069262; called by muse, mutect2, varscan2
- CEP350 | c.4011C>T p.N1337= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs768576547, COSV62604294; called by mutect2, varscan2
- POLR1F | c.801G>A p.A267= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as rs746171640, COSV55997996, COSV55998463; called by muse, mutect2, varscan2
- PYHIN1 | c.51C>A p.I17= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as rs112095976, COSV63722828; called by muse, mutect2, varscan2
- RBP3 | c.588G>T p.V196= | Silent (SNP) | VAF 20/158 reads (13%) | called by muse, mutect2, varscan2
- RCVRN | c.258C>T p.Y86= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs764982768, COSV56841335, COSV99874156; called by muse, mutect2, varscan2
- SPEG | c.5439C>T p.N1813= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs1559414834, COSV100404413; called by muse, varscan2
- STK38 | c.90T>C p.F30= | Silent (SNP) | VAF 35/201 reads (17%) | catalogued as COSV57709259; called by muse, mutect2, varscan2
- TRPC5 | c.2430G>A p.G810= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV53293465; called by muse, mutect2, varscan2
- ZNF48 | c.198T>G p.S66= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs957703144, COSV60783471; called by muse, mutect2, varscan2
- ZNF799 | c.183A>G p.K61= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
